Gene-level copy-number profile of tumor specimen TCGA-L5-A88S-01A from TCGA case TCGA-L5-A88S, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IB; Tumor grade: GX; Age at diagnosis: 84.7 years (30,954 days).
Specimen TCGA-L5-A88S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.11aae376-b70b-414f-a0cd-43e25ff29b96.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A88S-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aed649a6-2c59-4290-b9a9-28ea613c0c31

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 22,022; copy number 2: 33,088; copy number 3: 2,318; copy number 4: 1,268; copy number 5: 461; copy number 6: 128; copy number 7: 103; copy number 8: 100; copy number 9: 29; copy number 10: 28; copy number 11: 39; copy number 12: 41; copy number 16: 58; copy number 20: 23; copy number 22: 9; copy number 26: 14; copy number 27: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A88S-01A-11D-A36I-01): tumor purity 0.46, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,838,903–90,839,037, 1 gene: TMSB4XP8.
- chr9:21,409,117–22,214,672, 27 genes: IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr13:66,302,834–69,408,735, 27 genes: PCDH9, PCDH9-AS1, RNU7-87P, PCDH9-AS2, PCDH9-AS3, PCDH9-AS4, AL160254.1, RPSAP53, LINC00364, AL512452.1, BCRP9, NPM1P22, OR7E111P, OR7E33P, AL590027.1, ELL2P3, HNRNPA1P18, RPL37P21, RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4, SNRPFP3, LINC00383, SRSF1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,065 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:151,409,883–152,649,826, 15 genes, copy number 6 (within-gene range 2–6): RIF1, NEB, ARL5A, AC097448.1, AC068547.1, CACNB4, AC079790.1, STAM2, RPL30P2, AC079790.2, Y_RNA, FMNL2, NUDCP1, AC012066.1, AC012443.1.
- chr2:203,867,771–204,507,672, 9 genes, copy number 7: CTLA4, ICOS, AC009965.2, AC009965.1, AC009498.1, DSTNP5, AC106901.1, AC016903.1, AC016903.2.
- chr2:204,668,863–204,678,698, 1 gene, copy number 7: AC007736.1.
- chr3:169,709,295–172,725,038, 72 genes, copy number 16–27 (broad region; genes not listed).
- chr5:58,198–29,600,868, 446 genes, copy number 5–6 (broad region; genes not listed).
- chr6:43,671,202–44,553,281, 32 genes, copy number 6: MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642, AL136140.1, AL136140.2.
- chr7:91,264,433–92,134,803, 9 genes, copy number 6–9 (within-gene range 3–9): FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1.
- chr7:98,106,862–99,679,998, 41 genes, copy number 12 (within-gene range 1–12): LMTK2, BHLHA15, TECPR1, BRI3, BAIAP2L1, AC093799.1, RPS3AP26, PPIAP82, AC074121.1, NPTX2, RNU6-393P, TMEM130, TRRAP, MIR3609, AC004893.2, RNF14P3, SMURF1, AC004893.1, KPNA7, MYH16, AC004834.1, AC004922.1, ARPC1A, ARPC1B, PDAP1, BUD31, PTCD1, ATP5MF-PTCD1, CPSF4, AC073063.1, ATP5MF, ZNF789, ZNF394, ZKSCAN5, FAM200A, ZNF655, AC005020.2, TMEM225B, ZSCAN25, AC005020.1, CYP3A5.
- chr11:69,641,156–70,436,584, 27 genes, copy number 11: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,706,068, 6 genes, copy number 11: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr12:14,169,746–28,825,831, 236 genes, copy number 5–16 (broad region; genes not listed).
- chr12:66,116,555–75,432,688, 154 genes, copy number 7–22 (broad region; genes not listed).
- chr13:63,667,681–65,973,699, 17 genes, copy number 6–11: LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P, AL445238.1, LINC00355, NFYAP1, LGMNP1, STARP1, HNRNPA3P5, LINC01052, AL158038.1, MIR548X2.

Autosomal genes at a single copy (total copy number 1): 19,601. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
